Gene-level copy-number profile of tumor specimen MP2PRT-PAWBKV-TMP1-A from MP2PRT case MP2PRT-PAWBKV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.5 years (3,096 days).
Specimen MP2PRT-PAWBKV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1c1c9807-b0a1-476c-8f6e-6803da761a66.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAWBKV-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/20e3c9ba-57c7-4723-8133-79138b447871

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 127; copy number 1: 1,201; copy number 2: 56,513; copy number 3: 143; copy number 4: 294; copy number 5: 109.

Homozygous deletions (total copy number 0; autosomes only): 127 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:156,192,063–156,456,763, 16 genes: AL135927.1, SLC25A44, PMF1-BGLAP, PMF1, BGLAP, PAQR6, SMG5, TMEM79, GLMP, VHLL, CCT3, TSACC, RHBG, AL139130.1, MIR9-1HG, MIR9-1.
- chr1:190,478,551–190,801,658, 5 genes: LINC01351, AL391645.1, LINC01720, AL139135.1, AL139135.2.
- chr1:220,528,136–220,664,461, 1 gene (within-gene range 0–2): MARK1.
- chr1:220,625,740–220,885,059, 11 genes: HDAC1P2, C1orf115, MTARC2, MTARC1, AL445423.3, RNU6ATAC35P, AL445423.2, AL445423.1, LINC01352, HLX-AS1, HLX.
- chr9:18,717,974–18,718,526, 1 gene (within-gene range 0–1): RAP1BP1.
- chr9:19,507,452–26,118,408, 93 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 109 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,676,851–151,699,091, 109 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,201. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
